Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EI-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1 - "Biopsy of cervix":
Invasive squamous cell carcinoma.

ICD-O 3
Carcinoma, squamous cell NOS
8870/3
Site Cervix NOS
C53.9
JW 11/21/13

Source: NCI Genomic Data Commons file a8a26f9f-1d15-4b77-9ff5-1b53090867e6 (TCGA-VS-A8EI.B9B4DCAB-A369-496B-B36B-9E16041FD940.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).